Somatic mutation profile of tumor specimen TCGA-CG-4462-01A (aliquot TCGA-CG-4462-01A-01D-1158-08) from TCGA case TCGA-CG-4462, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 72.6 years (26,511 days).
Specimen TCGA-CG-4462-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2ca55fc-8ee8-42b9-ada5-e1e61adcdd0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4462-10A (Blood Derived Normal), aliquot TCGA-CG-4462-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e169bae-f668-4927-8eef-973d8dd08c30

The open-access MAF lists 64 somatic variants for this specimen: 45 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 39, Silent 19, Nonsense Mutation 5, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NIPBL | c.7219C>T p.R2407* | Nonsense Mutation (SNP) | VAF 22/198 reads (11%) | catalogued as rs398124471, CM073232, COSV56956936; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.1391C>G p.S464* | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- TTLL5 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 17/320 reads (5%) | catalogued as rs1439202144, COSV54028776, COSV54037759; ClinVar: likely pathogenic; called by muse, mutect2
- ADGRV1 | c.3478G>T p.D1160Y | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV67989233, COSV67993711; called by muse, mutect2
- ATP6AP2 | c.1039C>T p.R347* (on ENST00000378438; = p.R348* on NM_005765.3) | Nonsense Mutation (SNP) | VAF 19/182 reads (10%) | catalogued as COSV65797151; called by muse, mutect2, varscan2
- CAND2 | c.2474G>A p.R825H (on ENST00000456430 / NM_001162499.2; = p.R732H on NM_012298.3) | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as rs747643034, COSV55991744; called by muse, mutect2, varscan2
- CCDC81 | c.1256C>T p.A419V (on ENST00000445632 / NM_001156474.2; = p.A329V on NM_021827.4) | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as rs766513360, COSV53579586; called by muse, mutect2, varscan2
- CEP128 | c.2731T>C p.S911P | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV55382127; called by muse, mutect2
- COG3 | c.1846C>T p.L616F | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63073842; called by muse, mutect2
- COL14A1 | c.4417C>T p.R1473* | Nonsense Mutation (SNP) | VAF 23/183 reads (13%) | catalogued as COSV52853392, COSV99921067; called by muse, mutect2, varscan2
- CSMD1 | c.9422G>A p.R3141H (on ENST00000520002; = p.R3140H on NM_033225.6) | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs768149539, COSV59277588; called by muse, mutect2
- CTNNA2 | c.2714C>T p.S905F (on ENST00000402739 / NM_001282597.3; = p.S857F on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV58161923; called by muse, mutect2
- EFL1 | c.495C>G p.H165Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.246); catalogued as COSV51607292; called by muse, mutect2, varscan2
- FAM186B | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV57722112; called by muse, mutect2
- FBXO40 | c.1721C>A p.T574N | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs1225905405, COSV57525429; called by muse, mutect2, varscan2
- FHOD1 | c.3014G>A p.R1005H | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1039772478, COSV50763392; called by muse, mutect2, varscan2
- GAL3ST1 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV100143286; called by muse, varscan2
- GAL3ST4 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs145166071; called by muse, mutect2, varscan2
- GPR17 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.551); catalogued as rs562945179, COSV55754255; called by muse, mutect2
- ICAM5 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.871); catalogued as COSV53425876; called by muse, mutect2
- INHBA | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54222870, COSV54223275; called by muse, mutect2, varscan2
- KLB | c.2808G>T p.E936D | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV57302838; called by muse, mutect2, varscan2
- LRGUK | c.2192A>G p.E731G | Missense Mutation (SNP) | VAF 29/291 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV53640036; called by muse, mutect2
- MAGEB18 | c.352T>G p.L118V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57464460; called by muse, mutect2
- MYO3A | c.3145A>C p.N1049H | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56327897; called by muse, mutect2, varscan2
- NCAPD2 | c.3253C>T p.R1085C | Missense Mutation (SNP) | VAF 76/660 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs199911941; called by muse, mutect2, varscan2
- NME8 | c.51A>C p.Q17H | Missense Mutation (SNP) | VAF 39/473 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52252375; called by muse, mutect2
- NOX1 | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs757688304, COSV54194326; called by muse, mutect2, varscan2
- OR2B2 | c.806A>G p.D269G | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV57580110; called by muse, mutect2
- ORM1 | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.15); catalogued as COSV52279975; called by muse, mutect2, varscan2
- PDS5A | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57827860; called by muse, mutect2
- PGM5 | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs201672908, COSV67168317; called by muse, mutect2
- PHLPP2 | c.789G>C p.E263D | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as COSV62425410; called by muse, mutect2
- PLXNA4 | c.4943G>C p.G1648A | Missense Mutation (SNP) | VAF 27/587 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58104240, COSV58140020; called by muse, mutect2
- PZP | c.1504G>A p.V502I | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs796052146, COSV54364129; called by muse, mutect2, varscan2
- RETSAT | c.151A>T p.R51W | Missense Mutation (SNP) | VAF 45/508 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55527018; called by muse, mutect2
- SALL3 | c.3241C>T p.P1081S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV73306203; called by muse, mutect2, varscan2
- SIGLEC12 | c.1194C>A p.H398Q (on ENST00000291707 / NM_053003.4; = p.H280Q on NM_033329.2) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.089); catalogued as COSV52462888; called by muse, mutect2, varscan2
- SLC25A5 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.693); catalogued as COSV58627645; called by muse, mutect2, varscan2
- SLITRK5 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.233); catalogued as rs1449242517, COSV61521420; called by muse, mutect2
- SPTA1 | c.6506T>C p.F2169S | Missense Mutation (SNP) | VAF 29/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63756038; called by muse, mutect2
- TECPR2 | c.2683G>C p.V895L | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.162); catalogued as rs764000123, COSV63971726; called by muse, mutect2
- TEX15 | c.4406_4407insC p.K1469Nfs*13 (on ENST00000256246; = p.K1852Nfs*13 on NM_001350162.2) | Frame Shift Ins (INS) | VAF 16/148 reads (11%) | catalogued as COSV99822375; called by mutect2, varscan2
- TRIM62 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs780488792, COSV52222160; called by muse, mutect2, varscan2
- TRBV19 | c.287C>G p.T96S | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2
- ATP6V1E2 | c.294G>A p.A98= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as rs147271327; called by muse, mutect2
- ATXN7L2 | c.168G>A p.L56= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as COSV63992498; called by muse, mutect2, varscan2
- C6orf15 | c.426G>A p.A142= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as rs531449119, COSV52538893; called by muse, mutect2, varscan2
- CHL1 | c.483T>G p.P161= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as COSV56597297; called by muse, mutect2
- CNTNAP4 | c.276C>A p.T92= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs138220882, COSV56689011; called by muse, mutect2, varscan2
- EML1 | c.1491G>T p.T497= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV51746485, COSV51748123; called by muse, mutect2
- KIAA1549L | c.4764G>A p.S1588= (on ENST00000321505; = p.S1885= on NM_012194.3) | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs929035341, COSV100381197, COSV58582080; called by muse, mutect2
- LRP1B | c.13704T>C p.D4568= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as rs1361289702, COSV67243928; called by muse, mutect2
- PARP12 | c.1701C>T p.S567= | Silent (SNP) | VAF 14/189 reads (7%) | catalogued as rs145495111; called by muse, mutect2
- PHKA1 | c.543C>T p.F181= | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as rs781909169, COSV59807860; called by muse, mutect2
- PPARGC1A | c.1300C>T p.L434= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV53529921; called by muse, mutect2
- RAD51AP1 | c.657C>T p.D219= (on ENST00000228843 / NM_001130862.2; = p.D202= on NM_006479.5) | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as rs202224916, COSV57408884; called by muse, mutect2
- RIMS2 | c.1512C>T p.G504= (on ENST00000666250 / NM_001348490.2; = p.G312= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 22/156 reads (14%) | catalogued as rs758569920, COSV51656297; called by muse, mutect2, varscan2
- SENP6 | c.2388T>C p.C796= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV64188590; called by muse, mutect2, varscan2
- SETD4 | c.819C>T p.G273= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as COSV59772802; called by muse, mutect2, varscan2
- SKOR1 | c.543C>T p.F181= | Silent (SNP) | VAF 15/181 reads (8%) | catalogued as COSV58247429; called by muse, mutect2
- SPATA31D1 | c.3562A>C p.R1188= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV61197932; called by muse, mutect2
- TACR3 | c.393C>T p.D131= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as rs200691126, COSV59203877; called by muse, mutect2, varscan2
- TMEFF2 | c.156C>T p.T52= | Silent (SNP) | VAF 31/273 reads (11%) | catalogued as rs1161723733, COSV55835248; called by muse, mutect2, varscan2
